Surgical pathology report (de-identified scan), TCGA case TCGA-AO-A0JJ, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site MSKCC, specimen TCGA-AO-A0JJ-01A (Primary Tumor).

[page 1 of 6]
Clinical Diagnosis & History:

y/o female with biopsy proven left ILC at mastectomy and SLN/possible ALND. Scheduled for left total

Specimens Submitted:

- 1: SP: Sentinel node #1, level 1, left axilla (fs)
- 2: SP: Sentinel node #2, level 2, left axilla (fs)
- 3: SP: Sentinel node #3, level 2, left axilla (fs)
- 4: SP: Sentinel node #4, level 1, left axilla (fs)
- 5: SP: Left breast (sr)
- 6: SP: Non-sentinel node level 1, left axilla
- 7: SP: Left axillary contents level 1
- 8: SP: Left axillary contents level 2 and tag

DIAGNOSIS:

- 1) LYMPH NODE, SENTINEL #1 LEVEL I LEFT AXILLA; BIOPSY:
- METASTATIC MAMMARY CARCINOMA INVOLVING ONE OF ONE LYMPH NODE (1/1).
- NO EXTRANODAL TUMOR EXTENSION IS PRESENT.
- 2) LYMPH NODE, SENTINEL #2 LEVEL II LEFT AXILLA; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 3) LYMPH NODE, SENTINEL #3 LEVEL II LEFT AXILLA; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 4) LYMPH NODE, SENTINEL #4 LEVEL I LEFT AXILLA; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 5) BREAST, LEFT; MASTECTOMY:
- INVASIVE LOBULAR CARCINOMA, CLASSICAL TYPE, DIFFUSELY INVOLVING THE SUBMITTED TISSUE SECTIONS. THE LARGEST DIMENSION OF THE INVASIVE CARCINOMA CANNOT BE ACCURATELY DETERMINED BECAUSE OF ITS DIFFUSE NATURE, BUT BASED ON GROSS EXAMINATION IT IS ESTIMATED THAT THE INVASIVE CARCINOMA SPANS AN AREA OF ABOUT 4.5 CM.
- THE BASE OF THE NIPPLE IS ALSO INVOLVED BY INVASIVE LOBULAR CARCINOMA.
- LOBULAR CARCINOMA IN SITU (LCIS).
- MICROCALCIFICATIONS ARE PRESENT IN BENIGN (ENTRAPPED) BREAST PARENCHYMA.
- LYMPHOVASCULAR INVASION IS PRESENT.
- NO INVOLVEMENT OF THE SURGICAL MARGINS BY CARCINOMA IS IDENTIFIED.

** Continued on next page **

ICB-0-3
carcinoma, infiltrating lobular, NOS
8520/3
Site: breast, NOS c50.9 lw
10/24/11

[page 2 of 6]
- SKIN WITH SCAR.
- THE REMAINING NON-NEOPLASTIC BREAST TISSUE SHOWS BIOPSY SITE CHANGES AND FOCAL DUCTAL HYPERPLASIA WITH FOCAL ATYPIC.
- ONE AXILLARY LYMPH NODE IS POSITIVE FOR METASTATIC MAMMARY CARCINOMA (1/1). - NO EXTRANODAL TUMOR EXTENSION IS PRESENT.
- RESULTS OF IMMUNOHISTOCHEMICAL STAINS ARE AS FOLLOWS:
ER: 95% NUCLEAR STAINING WITH STRONG INTENSITY
PR: 70% NUCLEAR STAINING WITH MODERATE TO STRONG INTENSITY
HER-2/NEU (HERCEPT): NEGATIVE (STAINING INTENSITY OF 0)

- 6) LYMPH NODE, NON-SENTINEL LEVEL I LEFT AXILLA; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 7) LYMPH NODES, LEFT AXILLARY CONTENTS LEVEL I; DISSECTION:
- TWENTY-TWO BENIGN LYMPH NODES (0/22).
- 8) LYMPH NODES, LEFT AXILLARY CONTENTS LEVEL II; DISSECTION:
- SIXTEEN BENIGN LYMPH NODES (0/16).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	RECUT	
	ER-C	
	PR-C	
	HER2-C	
	NEG CONT	
	IMM RECUT	
	NEG-HER2	
	RECUT	

Gross Description:

- 1) The specimen is received fresh and is labeled "Sentinel node #1 level 1 axilla" and consists of one lymph node measuring 1.5 x 0.8 x 0.4 cm. Bisected and entirely submitted for frozen section.

Summary of sections:

FSC - frozen section control

- 2) The specimen is received fresh, labeled "Sentinel node #2 level 2 left axilla" and consists of one lymph node measuring 0.8 x 0.5 x 0.3 cm.

** Continued on next page **

[page 3 of 6]
----- Page 3 of 6
Entirely submitted for frozen section.

Summary of sections:
FSC - frozen section control

, M.D.

3) The specimen is received fresh, labeled "Sentinel node #3 level 2 left axilla" and consists of one lymph node measuring 1.0 x 0.5 x 0.3 cm. Entirely submitted for frozen section.

Summary of sections:
FSC - frozen section control

, M.D.

4) The specimen is received fresh and is labeled "Sentinel node #4 level 1 left axilla" and consists of a lymph node measuring 1.5 x 0.5 x 0.4 cm. Entirely submitted for frozen section.

Summary of sections:
FSC - frozen section control

M.D.

5) The specimen is received fresh labeled, "Left breast, stitch marked axillary tail" and consists of a breast with attached axillary tail. The breast measures 35.5 x 24.0 x 3.8 cm with overlying skin ellipse measuring 13.5 x 7.5 cm. Situated centrally on the skin surface is an unremarkable nipple measuring 1.2 x 1.2 x 0.8 cm and areola measuring 3.9 x 3.9 cm. The skin shows a linear scar measuring 8.0 cm, situated vertically near the nipple. A suture demarcates the axillary tail which measures 4.5 x 3.5 x 3.5 cm. Sectioning the breast reveals a biopsy cavity, measuring 4.2 x 3.5 x 4.0 cm with a fibrotic area superior to the cavity. One ill-defined tan mass is present, measuring 4.5 x 4.5 x 2.7 cm, located lateral to the nipple in UOQ and 3.5 cm from the deep surgical margin. The remaining breast tissue shows unremarkable intermingling of fatty and fibrotic areas. The axillary tissue is dissected to reveal one lymph node, measuring 1.1 x 0.5 x 0.5 cm. Representative sections are submitted. A portion of tumor is submitted to

Summary of sections:

N - nipple
NB - nipple base
S - skin scar
D - deep margin
T - tumor
UIQ - upper inner quadrant
LIQ - lower inner quadrant
UOQ - upper outer quadrant
LOQ - lower outer quadrant
LNS - lymph node

** Continued on next page **

[page 4 of 6]
M.D.

6) The specimen is received in formalin is labeled "Non-sentinel node level 1 left axilla" and consists of a tan soft lymph node measuring 1.0 x 1.0 x 0.7 cm. Entirely submitted.

Summary of sections:

LN - lymph node (bisected)

, M.D.

7) The specimen is received in formalin and is labeled "Left axillary contents level 1" and consists of multiple lymph nodes and fat measuring 8.0 x 7.0 x 1.1 cm in aggregate. The lymph nodes measure from 0.2 cm to 3.0 cm in greatest dimension. The lymph nodes are entirely submitted.

Summary of sections:

BLN1 - bisected lymph node

BLN2 - bisected lymph node

LN - lymph nodes

, M.D.

8) The specimen is received in formalin labeled "Left axillary contents level 2 and tag" and consists of multiple lymph nodes and attached fat measuring 5.0 x 4.0 x 0.6 cm. The lymph nodes measure from 0.3 cm to 0.5 cm in greatest dimension. The lymph nodes are entirely submitted.

Summary of sections:

LN - lymph nodes

Summary of Sections:

Part 1: SP: Sentinel node #1, level 1, left axilla (fs)

Block	Sect.	Site	PCs
1	fsc		1

Part 2: SP: Sentinel node #2, level 2, left axilla (fs)

Block	Sect.	Site	PCs
1	fsc		1

Part 3: SP: Sentinel node #3, level 2, left axilla (fs)

Block	Sect.	Site	PCs
1	fsc		1

Part 4: SP: Sentinel node #4, level 1, left axilla (fs)

** Continued on next page **

[page 5 of 6]
Block	Sect.	Site	PCs
1	fsc		1

Part 5: SP: Left breast

Block	Sect.	Site	PCs
1	dm		1
2	liq		2
1	lms		1
2	loq		2
1	n		1
1	nb		1
1	sk		1
5	t		5
2	uiq		2
2	uoq		2

Part 6: SP: Non-sentinel node level 1, left axilla

Block	Sect.	Site	PCs
1	ln		1

Part 7: SP: Left axillary contents level 1

Block	Sect.	Site	PCs
2	bln1		2
2	bln2		2
6	ln		6

Part 8: SP: Left axillary contents level 2 and tag

Block	Sect.	Site	PCs
3	ln		3

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS METASTATIC CARCINOMA.
PERMANENT DIAGNOSIS: SAME
- 2) FROZEN SECTION DIAGNOSIS NO CARCINOMA IDENTIFIED.
PERMANENT DIAGNOSIS: SAME
- 3) FROZEN SECTION DIAGNOSIS NO CARCINOMA IDENTIFIED.
PERMANENT DIAGNOSIS: SAME
- 4) FROZEN SECTION DIAGNOSIS NO CARCINOMA IDENTIFIED.
PERMANENT DIAGNOSIS: SAME

** Continued on next page **

[page 6 of 6]
** End of Report **

Source: NCI Genomic Data Commons file 188b3e18-7fab-4bf5-a0a5-291c2cf47816 (TCGA-AO-A0JJ.EB9B6625-6674-4665-9BEE-D4DFD9366A02.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).